Somatic mutation profile of tumor specimen C3N-01410-02 (aliquot CPT0117970009) from CPTAC case C3N-01410, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.2 years (23,442 days).
Specimen C3N-01410-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c494b0b4-0e89-415e-b4bb-74d38c9b1b0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01410-31 (Blood Derived Normal), aliquot CPT0119210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fccac375-3af5-4531-9f08-339ec3d0736c

The open-access MAF lists 333 somatic variants for this specimen: 217 protein-altering or splice-affecting, 59 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 59, Intron 30, Nonsense Mutation 14, RNA 9, 3'UTR 7, 5'UTR 6, Splice Region 5, Splice Site 4, 5'Flank 4, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 133/343 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.374+1A>G p.X125_splice | Splice Site (SNP) | VAF 55/188 reads (29%) | hotspot (GDC flag); catalogued as rs1131690951, CS021376, COSV58820569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772229711, COSV100312290; called by muse, mutect2, varscan2
- ADAMTS10 | c.2778C>A p.S926R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs782516100; called by muse, mutect2, varscan2
- ADGRE2 | c.1505C>A p.T502K | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs1481007699; called by muse, mutect2, varscan2
- AFAP1L2 | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100412819; called by muse, mutect2, varscan2
- AFF2 | c.2977A>T p.T993S | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV54011090; called by muse, mutect2, varscan2
- AKAP13 | c.8294C>T p.A2765V (on ENST00000394518 / NM_007200.5; = p.A2769V on NM_006738.6) | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs764900112; called by muse, mutect2, varscan2
- AMER1 | c.1490G>C p.R497P | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57668456; called by muse, mutect2, varscan2
- AMPD1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs140957303; called by muse, mutect2, varscan2
- ANKDD1A | c.1178C>G p.P393R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs561180507; called by muse, mutect2, varscan2
- APOB | c.10417G>A p.A3473T | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs150790543; called by muse, mutect2, varscan2
- ARNTL2 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs1204530577; called by muse, mutect2
- ARPP21 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51809973; called by muse, mutect2, varscan2
- ATM | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 99/204 reads (49%) | catalogued as COSV53769749; called by muse, mutect2, varscan2
- ATRNL1 | c.2654C>A p.P885Q | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.862); catalogued as rs202112185, COSV58085339; called by muse, mutect2
- CAST | c.1840A>G p.I614V (on ENST00000341926; = p.I697V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1265097638, COSV57091976; called by muse, mutect2, varscan2
- CCDC39 | c.1035-1G>T p.X345_splice | Splice Site (SNP) | VAF 61/122 reads (50%) | catalogued as COSV56477835; called by muse, mutect2, varscan2
- CDH18 | c.2284C>G p.Q762E | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.887); catalogued as COSV99931832, COSV99934322; called by muse, mutect2, varscan2
- COL11A2 | c.2070G>T p.P690= (on ENST00000341947 / NM_080680.3; = p.P583= on NM_080679.2) | Splice Region (SNP) | VAF 18/95 reads (19%) | catalogued as rs575638692, COSV100553977; called by muse, mutect2, varscan2
- COL22A1 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757243490, COSV57349375; called by muse, mutect2, varscan2
- CYP46A1 | c.327C>A p.Y109* | Nonsense Mutation (SNP) | VAF 28/326 reads (9%) | catalogued as rs772101757; called by muse, mutect2
- CYP4F12 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61172664; called by muse, mutect2, varscan2
- DCHS1 | c.6821G>T p.R2274L | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV55039515; called by muse, mutect2, varscan2
- DEFB135 | c.156A>T p.E52D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101198530; called by muse, mutect2, varscan2
- DIP2C | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs748869768, COSV55173603; called by muse, mutect2, varscan2
- DNPEP | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752488599; called by muse, mutect2, varscan2
- EPPK1 | c.4744C>T p.Q1582* | Nonsense Mutation (SNP) | VAF 41/169 reads (24%) | catalogued as COSV101599984; called by muse, mutect2, varscan2
- ESPNL | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772056400; called by muse, mutect2, varscan2
- FAM107B | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as COSV51688402; called by muse, mutect2, varscan2
- FCRL2 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs756244463, COSV63833280; called by muse, mutect2, varscan2
- FLG | c.6886G>A p.A2296T | Missense Mutation (SNP) | VAF 206/1085 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as rs1253908371; called by muse, mutect2, varscan2
- HNF4G | c.739G>T p.D247Y (on ENST00000354370 / NM_001330561.2; = p.D294Y on NM_004133.5) | Missense Mutation (SNP) | VAF 159/240 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469984727, COSV62965356; called by muse, varscan2
- ILK | c.699G>C p.R233S | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54991939; called by muse, mutect2, varscan2
- INHBC | c.967C>A p.R323S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs941858921; called by muse, mutect2
- IVL | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as rs750115245; called by muse, varscan2
- KCNT2 | c.3166G>C p.V1056L | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV54078440; called by muse, mutect2, varscan2
- KNTC1 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV61078946; called by muse, mutect2, varscan2
- LAIR1 | c.626+6G>T | Splice Region (SNP) | VAF 21/48 reads (44%) | catalogued as rs186375136; called by muse, mutect2, varscan2
- LINGO1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs763246298, COSV62437111; called by muse, mutect2, varscan2
- LIX1L | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 210/562 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs781919713; called by muse, mutect2, varscan2
- LRP1B | c.13106G>T p.C4369F | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67214469; called by muse, mutect2, varscan2
- MAGEB6B | c.1161C>A p.Y387* | Nonsense Mutation (SNP) | VAF 66/126 reads (52%) | catalogued as COSV69689772; called by muse, mutect2, varscan2
- MLLT10 | c.1903C>G p.L635V (on ENST00000307729 / NM_001195626.3; = p.L651V on NM_004641.3) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100307401; called by muse, mutect2, varscan2
- MROH2B | c.3233C>A p.A1078D | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV101270762; called by muse, mutect2, varscan2
- MTSS2 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs748292625, COSV58697696; called by muse, mutect2, varscan2
- MYO9A | c.2312G>T p.R771L | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV100613955, COSV61849453; called by muse, mutect2, varscan2
- NAV3 | c.5152G>T p.G1718W | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57111037; called by muse, mutect2, varscan2
- NPAP1 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.813); catalogued as COSV100276271; called by muse, mutect2, varscan2
- NRK | c.4213A>G p.T1405A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs1378907401, COSV54599280; called by muse, mutect2, varscan2
- OR2T11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs150548690; called by muse, mutect2, varscan2
- OR51A7 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs1564804869; called by muse, mutect2, varscan2
- OR52E8 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV66204679; called by muse, mutect2, varscan2
- OR56A4 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58110073; called by muse, mutect2, varscan2
- OR5R1 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1188371796; called by muse, mutect2, varscan2
- OR8K1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as rs745749213; called by muse, mutect2, varscan2
- PAEP | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV52986244, COSV99057088; called by muse, mutect2, varscan2
- PAF1 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs376141484; called by muse, mutect2, varscan2
- PCDH15 | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 87/359 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV57352960; called by muse, mutect2, varscan2
- PCDHA13 | c.1440G>T p.Q480H | Missense Mutation (SNP) | VAF 87/606 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99164858; called by muse, mutect2, varscan2
- PCDHB8 | c.1973C>A p.T658K | Missense Mutation (SNP) | VAF 126/540 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); catalogued as rs781988348, COSV50754714, COSV50756627; called by muse, mutect2, varscan2
- PCDHGA8 | c.1766C>A p.T589N | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1199478937; called by muse, mutect2, varscan2
- POLG | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 170/535 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs775248939; called by muse, mutect2, varscan2
- PROM1 | c.1319T>A p.V440D | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101477080; called by muse, mutect2, varscan2
- PSG5 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61654946; called by muse, mutect2, varscan2
- RGS7 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.536); catalogued as rs1480200259; called by muse, mutect2, varscan2
- ROBO2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs777675875, COSV101533564; called by muse, mutect2, varscan2
- SFPQ | c.1130A>G p.N377S | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1324288871, COSV61759370; called by muse, mutect2, varscan2
- SFXN5 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763389266, COSV99729693; called by muse, mutect2, varscan2
- TENM3 | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 36/160 reads (23%) | catalogued as COSV69317711; called by mutect2, varscan2
- TMEM270 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 41/289 reads (14%) | catalogued as COSV57638998; called by muse, mutect2, varscan2
- TRPM5 | c.2194G>A p.V732M | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754942616, COSV50176685; called by muse, mutect2, varscan2
- UBASH3A | c.1051T>A p.Y351N | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV52312370; called by muse, mutect2, varscan2
- UBE3B | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV99783778; called by muse, mutect2
- ZAN | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.464); catalogued as rs1301080537, COSV61808691; called by muse, varscan2
- ZBTB33 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 115/190 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58533622; called by muse, mutect2, varscan2
- ZIC3 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV54974105; called by muse, mutect2, varscan2
- ZNF254 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100741578; called by muse, mutect2, varscan2
- ZNF257 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV71309455; called by muse, mutect2, varscan2
- ABCA1 | c.5786T>C p.V1929A | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ACSM2B | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ADAMTS20 | c.5275C>A p.Q1759K | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.1026G>T p.L342F (on ENST00000611781; = p.L286F on NM_052997.2) | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AP2A1 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AP3B1 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATXN2 | c.1012G>T p.V338L (on ENST00000550104; = p.V178L on NM_002973.4) | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- BAHCC1 | c.6855G>T p.K2285N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRCA2 | c.7473G>T p.Q2491H | Missense Mutation (SNP) | VAF 146/293 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf99 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN14 | c.950+1G>A p.X317_splice | Splice Site (SNP) | VAF 72/250 reads (29%) | called by muse, varscan2
- CBLB | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 169/396 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, varscan2
- CD1B | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CDHR1 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 197/593 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CES2 | c.154A>T p.N52Y | Missense Mutation (SNP) | VAF 135/282 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- CFTR | c.2549T>A p.L850H | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CGREF1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHL1 | c.3274C>A p.L1092I (on ENST00000397491 / NM_001253387.1; = p.L1108I on NM_006614.4) | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CMYA5 | c.8372C>A p.S2791Y | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CNBD1 | c.54C>G p.N18K | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- COL11A1 | c.3024+1G>T p.X1008_splice | Splice Site (SNP) | VAF 74/221 reads (33%) | called by muse, mutect2, varscan2
- CORIN | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPN1 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 63/505 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CPNE1 | c.475G>T p.D159Y (on ENST00000352393; = p.D164Y on NM_003915.5) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCFL | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 51/154 reads (33%) | called by muse, mutect2, varscan2
- CTSC | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 114/173 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CUL5 | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DCLRE1C | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDX17 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHRS7C | c.871C>A p.P291T (on ENST00000330255 / NM_001220493.2; = p.P290T on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.4257C>A p.V1419= | Splice Region (SNP) | VAF 122/300 reads (41%) | called by muse, mutect2, varscan2
- DNM3 | c.1338G>C p.L446= | Splice Region (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2, varscan2
- DOCK2 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DOCK3 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPEP1 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DSC1 | c.1835A>T p.D612V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DSP | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 192/567 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EML2 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EYS | c.4570A>T p.S1524C | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EYS | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM83C | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FAT4 | c.7965G>T p.E2655D | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FECH | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- FGD1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 109/214 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGFR4 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FHAD1 | c.3928G>T p.G1310* | Nonsense Mutation (SNP) | VAF 78/215 reads (36%) | called by muse, mutect2, varscan2
- FZD1 | c.1695G>T p.W565C | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA5 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GREB1 | c.5056C>A p.P1686T | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- GXYLT2 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- HDAC9 | c.197C>A p.A66E | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IFT27 | c.234G>T p.L78F (on ENST00000433985 / NM_001363003.2; = p.L77F on NM_006860.5) | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IMMT | c.2079T>A p.Y693* | Nonsense Mutation (SNP) | VAF 152/476 reads (32%) | called by muse, mutect2, varscan2
- ITGAX | c.2900T>A p.V967D | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KLHL33 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT18 | c.902G>C p.R301P | Missense Mutation (SNP) | VAF 77/541 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KRTAP10-2 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- LIX1L | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 208/562 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LRRTM3 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYZL2 | c.484A>G p.I162V (on ENST00000375318; = p.I116V on NM_183058.3) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- MAN1A2 | c.1784A>G p.E595G | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF6 | c.508G>C p.G170R | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MGAM2 | c.4186A>C p.N1396H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MINDY2 | c.1676_1680dup p.Y561Nfs*98 | Frame Shift Ins (INS) | VAF 16/110 reads (15%) | called by mutect2, pindel, varscan2
- MMP17 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, varscan2
- MYO7B | c.4072del p.H1358Tfs*70 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- NEB | c.8539G>T p.V2847L | Missense Mutation (SNP) | VAF 78/350 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NEK5 | c.1969T>A p.W657R | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPTN | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NSD1 | c.4950T>G p.N1650K | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSD1 | c.5662G>T p.D1888Y | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OIT3 | c.837G>C p.R279S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OR10AG1 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR10K2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 55/440 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2T10 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4Q2 | c.693G>C p.R231S | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PAX5 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDHB12 | c.2225C>G p.T742S | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PDZRN3 | c.1275G>T p.M425I | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PEX6 | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 100/329 reads (30%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1279C>A p.H427N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PIP4K2A | c.312G>T p.R104S | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- PKD2 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, varscan2
- PKP2 | c.1067C>A p.A356E | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLA1A | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PLXNB3 | c.2818G>A p.A940T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PLXNC1 | c.4343C>T p.A1448V | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLI | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- POM121L12 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRAMEF1 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PRRC2B | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM20 | c.3176C>A p.P1059Q | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- REEP4 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- RGS20 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 41/537 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2
- RGS7 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF6 | c.696G>T p.L232F | Missense Mutation (SNP) | VAF 129/226 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RRM1 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RWDD2A | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RYR2 | c.4783C>A p.L1595M | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SEMA5A | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 122/437 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SEPTIN14 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SERPINA4 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 70/673 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SIRT7 | c.407+8G>T | Splice Region (SNP) | VAF 58/292 reads (20%) | called by muse, mutect2, varscan2
- SLC30A8 | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC36A2 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SLC6A5 | c.2163G>T p.M721I | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by mutect2, varscan2
- SMAD1 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- SNRNP40 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SPEG | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SPEN | c.3044T>A p.L1015H | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SPON1 | c.488T>A p.I163N | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SRPK3 | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SSPN | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SVOP | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- SYNE1 | c.3954G>T p.E1318D (on ENST00000367255 / NM_182961.4; = p.E1325D on NM_033071.3) | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAOK1 | c.199A>T p.T67S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, varscan2
- TBX18 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, varscan2
- TCP11 | c.1322G>T p.G441V (on ENST00000512012; = p.G379V on NM_018679.5) | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEAD1 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TEX13C | c.1941C>A p.S647R | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, varscan2
- TIMELESS | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLCD1 | c.603dup p.T202Dfs*28 | Frame Shift Ins (INS) | VAF 47/308 reads (15%) | called by mutect2, pindel, varscan2
- TMC2 | c.2719T>A p.*907Rext*44 | Nonstop Mutation (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- TMCC3 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TNKS | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 197/389 reads (51%) | called by muse, mutect2, varscan2
- TNS2 | c.385T>A p.W129R (on ENST00000314250 / NM_170754.4; = p.W139R on NM_015319.2) | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBV2 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIM51GP | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- TTN | c.22511T>A p.F7504Y (on ENST00000591111; = p.F6577Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/193 reads (15%) | PolyPhen benign (0.132); called by muse, mutect2, varscan2
- VANGL2 | c.634T>A p.Y212N | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR90 | c.4298G>T p.G1433V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBBX | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZFHX4 | c.4593G>T p.M1531I | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ZNF160 | c.1780A>C p.K594Q | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF329 | c.732C>A p.Y244* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ZNF594 | c.1706G>T p.W569L | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF669 | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.895G>T p.V299L (on ENST00000252463; = p.V354L on NM_032805.3) | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ADAM21 | c.555G>A p.L185= | Silent (SNP) | VAF 130/268 reads (49%) | called by muse, mutect2, varscan2
- ANKS1B | c.2148G>T p.L716= | Silent (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- CADM3 | c.1182G>A p.K394= (on ENST00000368125 / NM_001127173.3; = p.K428= on NM_021189.5) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100929451, COSV63674697; called by muse, mutect2, varscan2
- CCDC168 | c.15090A>T p.T5030= | Silent (SNP) | VAF 62/203 reads (31%) | called by muse, mutect2, varscan2
- CDHR3 | c.1509G>T p.G503= | Silent (SNP) | VAF 79/250 reads (32%) | catalogued as COSV58423005; called by muse, mutect2, varscan2
- CHSY1 | c.1305C>T p.G435= | Silent (SNP) | VAF 78/253 reads (31%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.747G>T p.A249= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV70503897; called by muse, mutect2
- CRYGC | c.330C>A p.P110= | Silent (SNP) | VAF 88/262 reads (34%) | called by muse, mutect2, varscan2
- CTU1 | c.318G>T p.A106= | Silent (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- DBF4B | c.1458G>T p.A486= | Silent (SNP) | VAF 58/411 reads (14%) | called by muse, mutect2, varscan2
- DHRSX | c.396G>T p.V132= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- EFCAB3 | c.432A>G p.L144= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs1463862155; called by muse, mutect2, varscan2
- FOXD2 | c.448T>C p.L150= | Silent (SNP) | VAF 117/413 reads (28%) | catalogued as rs930070272, COSV58303426; called by muse, mutect2, varscan2
- FRYL | c.1134T>G p.T378= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- GPR101 | c.1407G>T p.L469= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- GPR37 | c.522C>T p.P174= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as rs758425463; called by muse, mutect2, varscan2
- GREB1L | c.3357C>A p.P1119= | Silent (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- GXYLT2 | c.237G>C p.A79= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1215271490; called by muse, mutect2, varscan2
- HTR7 | c.690G>T p.V230= | Silent (SNP) | VAF 58/200 reads (29%) | called by muse, mutect2, varscan2
- IGHM | c.741A>G p.T247= | Silent (SNP) | VAF 140/1039 reads (13%) | called by muse, mutect2, varscan2
- IGLV5-52 | c.42C>T p.C14= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs1334489208; called by muse, mutect2, varscan2
- ITGAX | c.2901C>A p.V967= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV99191856; called by muse, mutect2, varscan2
- KCNN3 | c.672G>C p.R224= | Silent (SNP) | VAF 48/224 reads (21%) | catalogued as COSV55211974; called by muse, mutect2, varscan2
- KCNT2 | c.3165T>A p.L1055= | Silent (SNP) | VAF 56/157 reads (36%) | called by muse, mutect2, varscan2
- KPRP | c.1158G>T p.R386= | Silent (SNP) | VAF 36/298 reads (12%) | called by muse, mutect2, varscan2
- LUM | c.558C>T p.L186= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as rs144214151, COSV99899194; called by muse, mutect2
- MMP17 | c.1017G>T p.V339= | Silent (SNP) | VAF 64/287 reads (22%) | called by muse, mutect2, varscan2
- MUC5B | c.8772T>C p.G2924= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- MUC5B | c.12879T>C p.S4293= | Silent (SNP) | VAF 46/252 reads (18%) | called by muse, mutect2, varscan2
- NCAM1 | c.1431C>A p.T477= (on ENST00000316851 / NM_181351.5; = p.T467= on NM_000615.7) | Silent (SNP) | VAF 88/152 reads (58%) | catalogued as COSV100378424; called by muse, mutect2, varscan2
- NRCAM | c.1917T>A p.T639= | Silent (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- OR2F2 | c.748C>T p.L250= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as rs752334026; called by muse, mutect2, varscan2
- OR4D9 | c.864G>C p.T288= | Silent (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- OR5D18 | c.816C>A p.V272= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as COSV100450427; called by muse, mutect2, varscan2
- PAPPA | c.4825C>A p.R1609= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV60292991; called by muse, mutect2, varscan2
- PCDH15 | c.2613A>T p.T871= | Silent (SNP) | VAF 71/411 reads (17%) | called by muse, mutect2, varscan2
- PDE4A | c.819G>T p.L273= (on ENST00000380702 / NM_001111307.2; = p.L34= on NM_006202.3) | Silent (SNP) | VAF 64/168 reads (38%) | called by muse, mutect2, varscan2
- PDGFRA | c.891G>A p.R297= | Silent (SNP) | VAF 69/378 reads (18%) | called by muse, mutect2, varscan2
- PKD2L1 | c.1677C>T p.I559= | Silent (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1647G>T p.R549= | Silent (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- PLPPR4 | c.2185C>A p.R729= | Silent (SNP) | VAF 68/191 reads (36%) | catalogued as rs1443444318, COSV64567875; called by muse, mutect2, varscan2
- PODNL1 | c.324G>T p.L108= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- PROC | c.507G>A p.G169= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV52165092; called by muse, mutect2, varscan2
- PSME3 | c.717C>A p.I239= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV53198477; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2055C>T p.N685= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as rs201637223; called by muse, mutect2, varscan2
- RAPGEFL1 | c.270G>T p.G90= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs995217788; called by muse, mutect2, varscan2
- SCN10A | c.3768G>T p.R1256= | Silent (SNP) | VAF 51/181 reads (28%) | called by muse, mutect2, varscan2
- SCN10A | c.1524G>T p.R508= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV71860877; called by muse, varscan2
- SLC12A7 | c.54G>T p.G18= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- SLC27A5 | c.1035G>T p.G345= | Silent (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- SLC4A4 | c.330G>C p.T110= (on ENST00000264485 / NM_001098484.3; = p.T66= on NM_003759.4) | Silent (SNP) | VAF 81/273 reads (30%) | called by muse, mutect2, varscan2
- SPEG | c.1728G>T p.P576= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- TTN | c.5982G>A p.S1994= (on ENST00000591111; = p.S1948= on NM_003319.4) | Silent (SNP) | VAF 42/259 reads (16%) | catalogued as rs573823772, COSV59887364; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBB1 | c.714C>A p.T238= | Silent (SNP) | VAF 98/340 reads (29%) | called by muse, mutect2, varscan2
- UBQLNL | c.363C>T p.P121= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs144353879; called by muse, mutect2, varscan2
- WDR64 | c.2418T>C p.D806= | Silent (SNP) | VAF 49/142 reads (35%) | called by muse, mutect2, varscan2
- WWC1 | c.3057G>T p.L1019= | Silent (SNP) | VAF 77/294 reads (26%) | called by muse, mutect2, varscan2
- ZBED5 | c.1164A>G p.L388= | Silent (SNP) | VAF 32/165 reads (19%) | catalogued as COSV69721402; called by muse, mutect2, varscan2
- ZNF578 | c.756C>A p.I252= | Silent (SNP) | VAF 102/206 reads (50%) | called by muse, mutect2, varscan2
- ABCC8 | c.1818-31G>T | Intron (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- AC011525.1 | n.1379G>T | RNA (SNP) | VAF 40/129 reads (31%) | catalogued as rs891764413; called by muse, mutect2, varscan2
- AC083899.1 | n.3339G>T | RNA (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- ADAM9 | c.*1409_*1410insA | 3'UTR (INS) | VAF 31/68 reads (46%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.-40C>T | 5'UTR (SNP) | VAF 74/199 reads (37%) | catalogued as rs746704795; called by muse, mutect2, varscan2
- AP001007.2 | n.166C>A | RNA (SNP) | VAF 46/408 reads (11%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4602G>T | Intron (SNP) | VAF 67/552 reads (12%) | catalogued as COSV100853460; called by muse, mutect2, varscan2
- AVPR2 | c.*333T>G | 3'UTR (SNP) | VAF 57/106 reads (54%) | called by muse, mutect2, varscan2
- CAGE1 | c.2292+656T>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- CASC15 | chr6:22146707 G>T | 5'Flank (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- CCL4L2 | c.191+92G>A | Intron (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- CFLAR | c.793+4318G>A | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as rs1057210681; called by muse, mutect2, varscan2
- CHCHD2P9 | n.126A>T | RNA (SNP) | VAF 72/173 reads (42%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+102C>T | Intron (SNP) | VAF 23/174 reads (13%) | catalogued as rs371163145, COSV52247749; called by muse, mutect2, varscan2
- DOCK4 | c.3402-483A>G | Intron (SNP) | VAF 86/259 reads (33%) | catalogued as rs1391052504; called by muse, mutect2, varscan2
- ELMO1 | c.1086+16C>A | Intron (SNP) | VAF 33/187 reads (18%) | catalogued as COSV60326482; called by muse, mutect2, varscan2
- ERICH3 | c.*1G>T | 3'UTR (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- GALNT17 | c.239-35124C>T | Intron (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- GRM6 | c.2436+43G>A | Intron (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2568G>A | RNA (SNP) | VAF 131/478 reads (27%) | called by muse, mutect2, varscan2
- GUK1 | c.-212T>C | 5'UTR (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- HAUS7 | chrX:153471007 G>T | 5'Flank (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- HEPACAM | c.427+14G>T | Intron (SNP) | VAF 153/289 reads (53%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2289C>A | RNA (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2
- HOXB3 | c.-298G>A | 5'UTR (SNP) | VAF 45/279 reads (16%) | catalogued as rs1380796306; called by muse, mutect2, varscan2
- IQCH | c.754-594A>G | Intron (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3342+19G>T | Intron (SNP) | VAF 47/326 reads (14%) | called by muse, mutect2, varscan2
- LINC02876 | n.253C>G | RNA (SNP) | VAF 73/273 reads (27%) | called by muse, mutect2, varscan2
- LRRC74A | c.217+130C>T | Intron (SNP) | VAF 148/273 reads (54%) | called by muse, mutect2, varscan2
- LY6K | c.218-597C>A | Intron (SNP) | VAF 40/160 reads (25%) | called by muse, mutect2, varscan2
- MAPK8 | c.689-689A>G | Intron (SNP) | VAF 19/174 reads (11%) | catalogued as rs373110828; called by muse, mutect2, varscan2
- MTA1 | c.*2G>T | 3'UTR (SNP) | VAF 100/231 reads (43%) | called by muse, mutect2, varscan2
- MYO1F | c.636+19G>A | Intron (SNP) | VAF 116/290 reads (40%) | catalogued as rs1216871468; called by muse, mutect2, varscan2
- NACA | c.71-4345C>A | Intron (SNP) | VAF 72/219 reads (33%) | called by muse, varscan2
- NACA | c.71-4346G>T | Intron (SNP) | VAF 74/225 reads (33%) | called by muse, varscan2
- NBPF25P | n.902G>T | RNA (SNP) | VAF 164/898 reads (18%) | called by muse, varscan2
- NDUFA10 | c.-39G>A | 5'UTR (SNP) | VAF 35/159 reads (22%) | called by muse, mutect2, varscan2
- OR5K2 | chr3:98501479 G>T | 3'Flank (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- PAFAH1B1 | c.-45G>T | 5'UTR (SNP) | VAF 71/258 reads (28%) | called by muse, mutect2, varscan2
- PRKCG | c.-178G>T | 5'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as rs760985936; called by muse, mutect2, varscan2
- RPL30 | c.21+13G>T | Intron (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- SCLY | c.802-200C>G | Intron (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- SCNN1A | chr12:6375593 A>T | 5'Flank (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2
- SFTPC | c.436-109G>A | Intron (SNP) | VAF 44/399 reads (11%) | called by muse, mutect2, varscan2
- SLC6A6 | c.229+10G>T | Intron (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- SNORD115-23 | n.44G>T | RNA (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- TBXAS1 | c.333+1761C>T | Intron (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- TDP1 | c.885-1373G>T | Intron (SNP) | VAF 119/236 reads (50%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480737 G>C | 5'Flank (SNP) | VAF 240/502 reads (48%) | catalogued as rs778353895, COSV100068083; called by muse, mutect2, varscan2
- TMEM255B | c.423+428C>A | Intron (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*559T>A | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-845T>A | Intron (SNP) | VAF 76/138 reads (55%) | called by muse, mutect2, varscan2
- TTN | c.4814+44A>T | Intron (SNP) | VAF 114/321 reads (36%) | called by muse, mutect2, varscan2
- UNC80 | c.938+941C>A | Intron (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2, varscan2
- WNK2 | c.6370+11G>A | Intron (SNP) | VAF 45/213 reads (21%) | catalogued as rs186537291; called by muse, mutect2, varscan2
- ZNF268 | c.*6468A>T | 3'UTR (SNP) | VAF 46/330 reads (14%) | called by muse, mutect2, varscan2
- ZNF594 | c.*590G>T | 3'UTR (SNP) | VAF 84/336 reads (25%) | called by muse, mutect2, varscan2
